Surgical pathology report (de-identified scan), TCGA case TCGA-QC-A7B5, project TCGA-SARC (Sarcoma), tissue source site Emory University, specimen TCGA-QC-A7B5-01A (Primary Tumor).

[page 1 of 3]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title:
Performed By:
Verified By:
Encounter info:

ICD-O-3
Sarcoma, pleomorphic
undifferentiated (8805/3)
Code to highest 8805/3
Site Scalp NOS (sarcoma, lipoma)
C49.0
QW 8/22/13

* Final Report *

(Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender:

M

Acc #:

(Age:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

SOFT TISSUE, SCALP MASS, RESECTION:

- PLEOMORPHIC UNDIFFERENTIATED SARCOMA, HIGH GRADE, SEE SYNOPTIC AND COMMENT.
- IMMUNOSTAINS ARE DIFFUSELY POSITIVE FOR SMA, FOCALLY POSITIVE FOR p63 AND NEGATIVE FOR DESMIN, S100-PROTEIN, SOX-10, HMWCK AND AE1/AE3.

Comment

Although p63 is focally positive, the histologic appearance is more in keeping with sarcoma than sarcomatoid carcinoma. Selected sections reviewed with who agrees with this assessment.

Electronically Signed by

Assisted by:

Printed by:

Printed on:

[page 2 of 3]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Synoptic Worksheet

A. Radical resection scalp sarcoma; short stitch-anterior; long stitch-lateral:

Preresection Treatment:	No therapy
Procedure:	Radical resection
Tumor Site:	Scalp
Histologic Type:	Undifferentiated pleomorphic high grade sarcoma
Histologic Grade:	Grade 3
Macroscopic Extent of Tumor:	Superficial - Subcutaneous/suprafascial
Tumor Size:	Greatest dimension: 2.2 cm Additional Dimension: 1.8 cm Additional Dimension: 0.4 cm
Margins:	Margin(s) positive for sarcoma Margin(s): Deep
Mitotic Rate:	44 /10 high-power fields (HPF)
Necrosis:	Not identified
Lymph-Vascular Invasion:	Not identified
Treatment Effect:	Not identified
Immunohistochemistry:	SMA and p63: POSITIVE; S100, SOX10, AE1/AE3, desmin and HMWCK: NEGATIVE
Cytogenetics:	Not performed
Molecular Pathology:	Not performed
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1a: Tumor 5 cm or less in greatest dimension, superficial tumor
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Number of nodes examined: 0 Number of nodes positive: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Necrotizing dermal granuloma; Fite, acid-fast, and GMS stains are negative

Clinical History

None provided.

Specimen(s) Received

A: Radical resection scalp sarcoma; short stitch-anterior; long stitch-lateral

Gross Description

The specimen is received fresh, labeled with the patient's name and medical record number designated as "radical resection scalp sarcoma; short stitch, anterior; long stitch, lateral" on the container and consists of an oriented circular skin excision (6.2 cm in diameter, excised to a depth of 0.8 cm) with a short stitch designating anterior and a long stitch designating lateral. Centrally located on the specimen is a bulging subcutaneous mass, 2.2 x 1.8 x 0.4 cm. The specimen is inked as follows: anterior, red; posterior, green; lateral, blue; medial, orange; deep, black. The subcutaneous mass is 2.5 cm from the anterior

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
-Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited. regarding

Anat Path Reports

* Final Report *

margin, 2.5 cm from the posterior margin, 2.2 cm from the lateral margin, and 2.4 cm from the medial margin. Sectioning reveal an ovoid red-tan soft mass with a greatest depth of 1.2 cm, less than 0.1 cm from the deep margin. Representative sections are submitted according to the cassette summary: Select tissue was submitted for Dictated by

CASSETTE SUMMARY:

A1-A10: Full thickness cross sections of specimen including mass (entirely), trisected, submitted anteriorly to posteriorly (central portion including mass in odd numbered cassettes, lateral and medial thirds in even numbered cassettes)

A11: Anterior margin, shaved

A12: Posterior margin, shaved

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file 7b2df7cc-8fa0-4308-b987-825203ac72d5 (TCGA-QC-A7B5.AF9DFFA6-AED9-481B-B2B1-9A65A3AD5E9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).